Somatic mutation profile of tumor specimen C3N-02429-01 (aliquot CPT0147280010) from CPTAC case C3N-02429, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 41.7 years (15,227 days).
Specimen C3N-02429-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 707cc182-abd8-4a25-b645-ba8f403a3276.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02429-71 (Blood Derived Normal), aliquot CPT0147310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c92d39-1145-4b03-a738-93d2659a3840

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1464del p.S489Afs*82 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | catalogued as rs1553644922; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADRA1D | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV65242043; called by muse, mutect2, varscan2
- CDKN2AIP | c.388A>T p.I130L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as COSV100187514; called by muse, mutect2, varscan2
- CFAP92 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.225); catalogued as rs754077147; called by muse, mutect2, varscan2
- DNAH17 | c.12583G>A p.E4195K | Missense Mutation (SNP) | VAF 80/548 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1314415630; called by muse, mutect2, varscan2
- DPY19L2 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61044435; called by muse, mutect2, varscan2
- NFE2L2 | c.806A>C p.N269T | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as rs749047359; called by muse, mutect2, varscan2
- PTRH2 | c.299_301del p.R100del | In Frame Del (DEL) | VAF 34/264 reads (13%) | catalogued as rs985248778; called by pindel, varscan2
- ZNF334 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 44/247 reads (18%) | catalogued as COSV100749241; called by muse, mutect2, varscan2
- ANKS4B | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 69/305 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- APC2 | c.808_816del p.N270_K272del | In Frame Del (DEL) | VAF 31/167 reads (19%) | called by mutect2, pindel
- CCDC61 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DPEP1 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KALRN | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- LCP1 | c.96T>G p.N32K | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MSS51 | c.1001A>C p.D334A | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NFXL1 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PSG8 | c.148_154del p.D50Ffs*32 | Frame Shift Del (DEL) | VAF 44/304 reads (14%) | called by mutect2, pindel, varscan2
- RCE1 | c.186-4_186-2delinsCC p.X62_splice | Splice Site (DEL) | VAF 46/277 reads (17%) | called by pindel, varscan2*
- SEZ6 | c.1855T>A p.C619S | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SNX17 | c.535T>G p.L179V | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- VHL | c.616dup p.I206Nfs*50 | Frame Shift Ins (INS) | VAF 89/417 reads (21%) | called by mutect2, pindel, varscan2
- ARAP3 | c.1266C>T p.Y422= | Silent (SNP) | VAF 91/459 reads (20%) | catalogued as rs1425606021; called by muse, mutect2, varscan2
- ARHGAP12 | c.162G>A p.K54= | Silent (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- BMP2K | c.2460C>T p.Y820= | Silent (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- FBN3 | c.2886C>T p.F962= | Silent (SNP) | VAF 109/533 reads (20%) | catalogued as COSV54461012, COSV99559313; called by muse, mutect2, varscan2
- GRK4 | c.1434C>A p.V478= (on ENST00000398052 / NM_182982.3; = p.V446= on NM_005307.3) | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- MYOCD | c.492G>A p.P164= | Silent (SNP) | VAF 55/347 reads (16%) | catalogued as rs745617618, COSV58507592; called by muse, mutect2, varscan2
- PATJ | c.4977A>G p.R1659= | Silent (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- TRIM15 | c.504G>A p.Q168= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as rs1288608260; called by mutect2, varscan2
- TTLL6 | c.2529G>A p.R843= (on ENST00000393382 / NM_001130918.3; = p.R536= on NM_173623.3) | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as rs1221948602; called by muse, mutect2, varscan2
- COL27A1 | c.5108-28C>T | Intron (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- NAA10 | c.179+27_179+36del | Intron (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- RBM39 | c.1226-712T>A | Intron (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1748C>T | Intron (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- TP73 | c.186+7746del | Intron (DEL) | VAF 110/529 reads (21%) | called by mutect2, pindel, varscan2
